Somatic mutation profile of tumor specimen TCGA-ZP-A9CY-01A (aliquot TCGA-ZP-A9CY-01A-11D-A382-10) from TCGA case TCGA-ZP-A9CY, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G1; Age at diagnosis: 66.3 years (24,223 days).
Specimen TCGA-ZP-A9CY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f8b36f1-b298-45fc-8b37-b4bb195e595e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZP-A9CY-10B (Blood Derived Normal), aliquot TCGA-ZP-A9CY-10B-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6427d26-f62b-431e-9b42-c43f32dc6101

The open-access MAF lists 93 somatic variants for this specimen: 71 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 17, Nonsense Mutation 4, Intron 4, Splice Region 2, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIN2A | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796052550, COSV58048141, COSV58055595; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABHD16B | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV99410932; called by muse, mutect2, varscan2
- ADAMTS12 | c.4579A>G p.N1527D | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as COSV100711799; called by muse, mutect2, varscan2
- ADGRG4 | c.3374A>G p.E1125G | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV99797482; called by muse, mutect2, varscan2
- ADGRG6 | c.3006A>T p.E1002D | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV99749325; called by muse, mutect2, varscan2
- ADGRV1 | c.13232T>A p.V4411E | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101316695; called by muse, mutect2, varscan2
- AP1M1 | c.95A>G p.H32R | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV99358736; called by muse, mutect2, varscan2
- BHLHE41 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.041); catalogued as COSV99658453; called by muse, mutect2, varscan2
- BRCA2 | c.7870T>A p.Y2624N | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101204721; called by muse, mutect2, varscan2
- CASK | c.2663A>T p.H888L (on ENST00000378163 / NM_001367721.1; = p.H883L on NM_003688.3) | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100587894; called by muse, mutect2, varscan2
- CGB8 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 28/311 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs924628224; called by muse, mutect2, varscan2
- COL4A3 | c.2636C>T p.P879L | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs368342782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.2881G>A p.G961R | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100880718; called by muse, mutect2, varscan2
- CSMD2 | c.915C>A p.V305= | Splice Region (SNP) | VAF 18/44 reads (41%) | catalogued as COSV99597009; called by muse, mutect2, varscan2
- DIS3L2 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as rs772470899, COSV99807579, COSV99807852; called by muse, mutect2, varscan2
- DISP1 | c.2925C>A p.D975E | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs760288803, COSV99452454; called by muse, mutect2
- DKC1 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 115/327 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV101059913; called by muse, mutect2, varscan2
- DNAH7 | c.2549G>T p.R850L | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100418200; called by muse, mutect2, varscan2
- DNAJC13 | c.5677C>T p.R1893* | Nonsense Mutation (SNP) | VAF 46/235 reads (20%) | catalogued as COSV53457606; called by muse, mutect2, varscan2
- DPP8 | c.2188C>T p.Q730* (on ENST00000341861 / NM_001320875.2; = p.Q714* on NM_130434.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/97 reads (32%) | catalogued as COSV100202683; called by muse, mutect2, varscan2
- DRC3 | c.1409A>G p.D470G | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV100572844; called by muse, mutect2, varscan2
- EEF1A1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.127); catalogued as COSV100303482; called by muse, mutect2, varscan2
- EGLN2 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100393888, COSV58281317; called by muse, mutect2, varscan2
- EPHA4 | c.872C>G p.A291G | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56037349, COSV99917765; called by muse, mutect2
- FAM155A | c.1346C>A p.T449K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV101030909; called by muse, mutect2, varscan2
- HEPHL1 | c.2608A>G p.K870E | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV100244604; called by muse, mutect2, varscan2
- HUWE1 | c.10561A>G p.T3521A | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV99474891; called by muse, mutect2, varscan2
- IL16 | c.3505T>C p.S1169P (on ENST00000302987 / NM_172217.5; = p.S468P on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100250965; called by muse, mutect2, varscan2
- IRS4 | c.1493G>A p.G498D | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.153); catalogued as COSV100929541; called by muse, mutect2, varscan2
- IRX4 | c.823C>G p.L275V | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV99039639; called by muse, mutect2, varscan2
- KANK1 | c.2864T>A p.L955Q | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100620177; called by muse, mutect2, varscan2
- KBTBD12 | c.281T>C p.L94S | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100675554; called by muse, mutect2, varscan2
- KIAA1958 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100516576; called by muse, mutect2, varscan2
- KLHL5 | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV54677107, COSV99786114; called by muse, mutect2, varscan2
- LYN | c.752A>G p.K251R | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.031); catalogued as COSV101319649; called by muse, mutect2, varscan2
- MAP3K1 | c.1224C>G p.I408M | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101267177; called by muse, mutect2, varscan2
- MTSS2 | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.37); catalogued as COSV99852047; called by muse, mutect2, varscan2
- MYO3A | c.3503C>A p.T1168N | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99782057; called by muse, mutect2, varscan2
- NRDE2 | c.1853A>T p.D618V | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100583722; called by muse, mutect2, varscan2
- OR5L1 | c.773T>G p.I258S | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV100450333; called by muse, mutect2, varscan2
- OR5M11 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV101602078; called by muse, mutect2, varscan2
- OR6B2 | c.797A>T p.D266V | Missense Mutation (SNP) | VAF 113/293 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.355); catalogued as COSV99401823; called by muse, mutect2, varscan2
- PCDHGB6 | c.2020G>T p.D674Y | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99549443; called by muse, mutect2, varscan2
- PKHD1L1 | c.10342G>C p.V3448L | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV101007135; called by muse, mutect2, varscan2
- POLR1D | c.277G>T p.V93F | Missense Mutation (SNP) | VAF 123/378 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); catalogued as COSV100265976; called by muse, mutect2, varscan2
- PPEF2 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); catalogued as COSV54422395; called by muse, mutect2, varscan2
- PRMT8 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs866613000, COSV54211723, COSV54217612; called by muse, mutect2, varscan2
- RANBP6 | c.483C>A p.H161Q | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.09); catalogued as COSV99424518; called by muse, mutect2, varscan2
- REG4 | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99858847; called by muse, mutect2, varscan2
- RTN1 | c.677A>G p.D226G | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs990013396, COSV99957187; called by muse, mutect2, varscan2
- SARAF | c.311C>G p.A104G | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99822951; called by muse, mutect2, varscan2
- SLC2A12 | c.727C>G p.L243V | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99260733; called by muse, mutect2, varscan2
- SLC34A1 | c.1158G>T p.Q386H | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100184191; called by muse, mutect2, varscan2
- SPN | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs762062584, COSV64070581; called by muse, mutect2, varscan2
- STX18 | c.922A>T p.N308Y | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV100086495; called by muse, mutect2, varscan2
- TBX4 | c.705C>A p.I235= | Splice Region (SNP) | VAF 18/160 reads (11%) | catalogued as COSV99540811; called by muse, mutect2, varscan2
- THOC2 | c.2969C>A p.A990E | Missense Mutation (SNP) | VAF 122/696 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV99834468; called by muse, mutect2, varscan2
- TPP2 | c.391-2A>T p.X131_splice | Splice Site (SNP) | VAF 53/125 reads (42%) | catalogued as COSV101060513; called by muse, mutect2, varscan2
- TRPA1 | c.1397T>C p.L466P | Missense Mutation (SNP) | VAF 97/508 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100085528; called by muse, mutect2, varscan2
- TUBA3E | c.968T>C p.V323A | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV99919972; called by muse, varscan2
- UBE2U | c.202C>G p.P68A | Missense Mutation (SNP) | VAF 47/634 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100934563; called by muse, mutect2
- WASHC3 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99527685; called by muse, mutect2, varscan2
- ZC3H7B | c.2177A>G p.K726R | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.137); catalogued as COSV100687926; called by muse, mutect2, varscan2
- ZFP57 | c.698G>A p.C233Y | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100972005; called by muse, mutect2, varscan2
- ZNF202 | c.616G>T p.V206F | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV100279197; called by muse, mutect2, varscan2
- ACVR2A | c.1418_1423del p.G473_C474del | In Frame Del (DEL) | VAF 51/144 reads (35%) | called by mutect2, pindel, varscan2
- ITIH4 | c.1558_1559del p.F520Pfs*47 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | called by mutect2, pindel, varscan2
- PGBD5 | c.422dup p.I142Dfs*47 (on ENST00000525115; = p.I211Dfs*47 on NM_001258311.2) | Frame Shift Ins (INS) | VAF 59/156 reads (38%) | called by mutect2, pindel, varscan2
- RCC1L | c.633_650+2del p.X211_splice | Splice Site (DEL) | VAF 230/898 reads (26%) | called by pindel, varscan2
- UMPS | c.765_782del p.C255_S261delins* | Nonsense Mutation (DEL) | VAF 35/148 reads (24%) | called by mutect2, pindel, varscan2
- XIRP2 | c.4356del p.E1453Kfs*8 (on ENST00000628543; = p.E1628Kfs*8 on NM_152381.6) | Frame Shift Del (DEL) | VAF 114/336 reads (34%) | called by mutect2, pindel, varscan2
- BPIFC | c.1180T>C p.L394= | Silent (SNP) | VAF 88/280 reads (31%) | catalogued as rs370427363; called by muse, mutect2, varscan2
- CACNA2D1 | c.817C>A p.R273= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs754162606, COSV100667634, COSV62379116; called by muse, mutect2, varscan2
- CCNB1 | c.972A>G p.K324= | Silent (SNP) | VAF 47/157 reads (30%) | catalogued as rs985671768, COSV99841412; called by muse, mutect2, varscan2
- ENTPD8 | c.951C>G p.V317= | Silent (SNP) | VAF 62/179 reads (35%) | catalogued as rs775700409, COSV58161962; called by muse, mutect2, varscan2
- ING1 | c.12G>T p.V4= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100312470; called by muse, mutect2, varscan2
- LOXL1 | c.1152T>C p.Y384= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV99985491; called by muse, mutect2, varscan2
- LRRC20 | c.447C>T p.I149= (on ENST00000355790 / NM_207119.3; = p.I93= on NM_018205.4) | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100714275; called by muse, mutect2, varscan2
- LTBP4 | c.3595C>A p.R1199= (on ENST00000308370 / NM_001042544.1; = p.R1162= on NM_003573.2) | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV99199807; called by muse, mutect2, varscan2
- OR1E2 | c.465G>A p.A155= | Silent (SNP) | VAF 28/192 reads (15%) | catalogued as COSV99943532; called by muse, mutect2, varscan2
- PCDH18 | c.693A>T p.I231= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV100787568; called by muse, mutect2, varscan2
- PCDHGB6 | c.135G>T p.S45= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as rs1191967573, COSV99549439; called by muse, mutect2, varscan2
- PTPN11 | c.987C>A p.A329= | Silent (SNP) | VAF 74/187 reads (40%) | catalogued as COSV100692913; called by muse, mutect2, varscan2
- RRBP1 | c.4014A>G p.L1338= (on ENST00000377813 / NM_001365613.2; = p.L905= on NM_004587.3) | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs1283892265, COSV99854837; called by muse, mutect2, varscan2
- SIDT2 | c.2340G>C p.S780= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as COSV54058866, COSV99638669; called by muse, mutect2, varscan2
- TRPC6 | c.2739T>C p.I913= | Silent (SNP) | VAF 55/153 reads (36%) | catalogued as rs756864306, COSV100723803; called by muse, mutect2, varscan2
- UBE2U | c.201T>A p.P67= | Silent (SNP) | VAF 46/634 reads (7%) | catalogued as COSV100934560; called by muse, mutect2
- ZNF415 | c.528A>G p.S176= | Silent (SNP) | VAF 28/149 reads (19%) | catalogued as COSV99702153; called by muse, mutect2, varscan2
- CCDC70 | c.-15C>T | 5'UTR (SNP) | VAF 11/80 reads (14%) | catalogued as rs200191823; called by muse, mutect2, varscan2
- PCSK5 | c.2626+3565C>A | Intron (SNP) | VAF 8/149 reads (5%) | catalogued as COSV65090929; called by muse, mutect2
- RGS3 | c.2037+4505G>T | Intron (SNP) | VAF 39/113 reads (35%) | catalogued as COSV100466097; called by muse, mutect2, varscan2
- SLIT3 | c.1459+4610C>G | Intron (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100270802; called by muse, mutect2, varscan2
- SORCS1 | c.3371+123T>C | Intron (SNP) | VAF 6/75 reads (8%) | catalogued as COSV99551319; called by muse, mutect2
